CCDI case PBCBAE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5c987ea2-f1ef-47fb-a8db-9a900822951e

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,441 days).

Biospecimens (3 samples)
- Sample 0DMWTP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMWTV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DMWU2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
